CPTAC case C3L-00009 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/208b87e8-f96f-419c-a659-c94a1b4c12b7

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1939; Vital status: Dead; Days to death: 577 days (1.6 years); Year of death: 2017; Country of birth: United States.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 76.6 years (27,968 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T1a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 577 days (1.6 years); Progression or recurrence: no; Days to last follow up: 545 days (1.5 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 1.8 cm (a second GDC size field records 7.5 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 10; Margin status: Uninvolved.

Follow-up (3 entries)
- Days to follow up: 423 days (1.2 years); Disease response: Tumor Free.
- Days to follow up: 545 days (1.5 years); Disease response: Complete Response.
- Days to follow up: 545 days (1.5 years); Disease response: Tumor Free.

Other clinical attributes
- Weight: 84.82 kg; Height: 171.98 cm; BMI: 28.67; Diabetes treatment type: Insulin.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 62; Cigarettes per day: 20; Tobacco smoking onset year: 1953; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 69.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00009-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -9 days; Initial weight: 225 mg; Time between excision and freezing: 10 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00009-21: Section location: Right Upper Lobe; Percent tumor nuclei: 50; Percent necrosis: 5.
- Sample C3L-00009-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -9 days; Initial weight: 338 mg; Time between excision and freezing: 10 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-00009-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -9 days; Method of sample procurement: Blood Draw.
